Gene-level copy-number profile of tumor specimen TCGA-CV-7433-01A from TCGA case TCGA-CV-7433, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 49.3 years (18,004 days).
Specimen TCGA-CV-7433-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b6e674c4-3dcd-40eb-8dcb-573431a9383a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7433-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2108eecd-cd13-4a03-b6ea-8c64a3700e0d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 11,136; copy number 2: 37,464; copy number 3: 8,507; copy number 4: 1,879; copy number 5: 622; copy number 6: 65; copy number 7: 8; copy number 8: 64; copy number 11: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7433-01A-11D-2128-01): tumor purity 0.3, ploidy 1.65, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 814 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:158,962,235–159,897,366, 1 gene, copy number 5 (within-gene range 4–5): IQCJ-SCHIP1.
- chr3:159,282,646–198,222,513, 686 genes, copy number 5–6 (broad region; genes not listed).
- chr11:68,460,731–68,615,334, 1 gene, copy number 11 (within-gene range 2–11): PPP6R3.
- chr11:68,612,899–70,398,488, 54 genes, copy number 11 (within-gene range 1–11): AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr14:22,066,016–22,505,167, 64 genes, copy number 8 (broad region; genes not listed).
- chr16:79,077,376–79,516,293, 8 genes, copy number 7: AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1, RNA5SP431, AC084064.1.

Autosomal genes at a single copy (total copy number 1): 8,724. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
